Somatic mutation profile of tumor specimen BA2113D (aliquot aq-BA2113D) from BEATAML1.0 case 2088, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.3 years (23,113 days).
Specimen BA2113D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df2414a0-569b-4f45-b77a-5fd0b8894bcf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2569D (Solid Tissue Normal), aliquot aq-BA2569D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98bd9d50-1ac1-4e00-bc96-ce249cf13df6

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Splice Region 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 30/54 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- IGHV1-58 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs376428980; called by muse, mutect2, varscan2
- PRAME | c.592A>G p.K198E | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.189); catalogued as rs1214736359; called by muse, mutect2, varscan2
- SPESP1 | c.251C>A p.S84* | Nonsense Mutation (SNP) | VAF 4/45 reads (9%) | catalogued as COSV52996282; called by muse, mutect2
- ALK | c.2364G>T p.Q788H | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CELSR2 | c.4963C>A p.Q1655K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2
- H4C8 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2
- MOB1B | c.35C>A p.T12N | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- TRIM51EP | n.744T>C | Splice Region (SNP) | VAF 30/192 reads (16%) | called by muse, mutect2, varscan2
- ZNF329 | c.74C>G p.T25R | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRT | c.1557C>T p.Y519= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs758233888, COSV61959443; called by muse, mutect2, varscan2
- TMEFF2 | c.315C>T p.S105= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV55841856; called by muse, mutect2, varscan2
- CDH11 | c.1895-642A>G | Intron (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
